Somatic mutation profile of tumor specimen C3L-06069-54 (aliquot CPT0326480002) from CPTAC case C3L-06069, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 79.2 years (28,924 days).
Specimen C3L-06069-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4a2fe8f-5b22-4215-b846-66e0b9de783f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06069-51 (Buccal Cell Normal), aliquot CPT0326580003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4419fd7-2c53-4462-8475-ab361f7f0f70

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 27/91 reads (30%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CLOCK | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs758354128; called by muse, mutect2
- FAM47A | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 93/221 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.659); catalogued as COSV60500448; called by muse, mutect2, varscan2
- PHB2 | c.607+7C>T | Splice Region (SNP) | VAF 11/69 reads (16%) | catalogued as rs781999865; called by muse, mutect2, varscan2
- PRICKLE1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.638); catalogued as rs776819993, COSV58207362; called by muse, mutect2, varscan2
- RBM26 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1352778278, COSV57391971; called by muse, mutect2
- RIMS2 | c.1222C>T p.R408* (on ENST00000666250 / NM_001348490.2; = p.R216* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/197 reads (14%) | catalogued as COSV99214086; called by muse, mutect2, varscan2
- SCN10A | c.4709C>T p.T1570M | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772484960, COSV101479190, COSV71860989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIN3A | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760260844, COSV64582527; called by muse, mutect2, varscan2
- TJP3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368423278, COSV53663633; called by muse, mutect2, varscan2
- FUBP1 | c.510del p.G171Efs*21 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- INVS | c.1955G>A p.G652D | Missense Mutation (SNP) | VAF 33/730 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TASOR2 | c.5524A>G p.R1842G | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF786 | c.1380G>C p.R460S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- ARG1 | c.240G>A p.L80= | Silent (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- NRG1 | c.1749T>G p.G583= (on ENST00000405005 / NM_013964.5; = p.G588= on NM_013956.5) | Silent (SNP) | VAF 82/317 reads (26%) | called by muse, mutect2, varscan2
- AC004080.3 | c.11-4482G>A | Intron (SNP) | VAF 27/410 reads (7%) | catalogued as rs1376409637; called by muse, mutect2
- GOLGA8IP | n.234G>A | RNA (SNP) | VAF 69/662 reads (10%) | catalogued as rs758537372; called by muse, mutect2, varscan2
